Somatic mutation profile of tumor specimen ALCH-ADHM-TTP1-A (aliquot ALCH-ADHM-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADHM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 37.6 years (13,746 days).
Specimen ALCH-ADHM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bfa397b-afd9-408e-a1d1-92cd9a23c5cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADHM-NB1-A (Blood Derived Normal), aliquot ALCH-ADHM-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b9b7433-9f50-41e6-86ff-e2d07d7a35d8

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, In Frame Del 2, 5'UTR 2, Frame Shift Del 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 88/786 reads (11%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 62/322 reads (19%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDR2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs754868982, COSV63370876; called by muse, mutect2, varscan2
- FASTKD3 | c.1892A>G p.Y631C | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1185433669; called by muse, mutect2
- HRH3 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 120/686 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.656); catalogued as rs199552270; called by muse, mutect2, varscan2
- MPO | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1317237427, COSV56562367; called by muse, mutect2, varscan2
- OCSTAMP | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.203); catalogued as rs1412424609, COSV54097420; called by muse, mutect2, varscan2
- TXNDC2 | c.1293G>C p.E431D (on ENST00000306084 / NM_001098529.2; = p.E364D on NM_032243.6) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV60156467; called by muse, mutect2, varscan2
- GUCA2B | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 139/959 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MIB2 | c.10_24del p.A4_G8del | In Frame Del (DEL) | VAF 73/385 reads (19%) | called by mutect2, pindel, varscan2
- PSKH1 | c.1033A>T p.T345S | Missense Mutation (SNP) | VAF 108/559 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PTEN | c.547_548del p.K183Efs*6 | Frame Shift Del (DEL) | VAF 35/234 reads (15%) | called by mutect2, pindel, varscan2
- RAB6B | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 124/601 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SLITRK6 | c.419del p.F140Sfs*11 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel, varscan2
- XKR3 | c.767T>C p.F256S | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ARPP21 | c.1926A>G p.P642= | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- CELSR1 | c.4653G>T p.G1551= | Silent (SNP) | VAF 103/705 reads (15%) | called by muse, mutect2, varscan2
- ESPN | c.2043C>T p.I681= | Silent (SNP) | VAF 260/1319 reads (20%) | catalogued as rs371653062, COSV64704247; called by muse, mutect2, varscan2
- FAM122A | c.306C>A p.V102= | Silent (SNP) | VAF 111/771 reads (14%) | called by muse, mutect2, varscan2
- SLC36A2 | c.1266C>T p.I422= | Silent (SNP) | VAF 45/356 reads (13%) | catalogued as rs768372175; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC6 | c.-99G>A | 5'UTR (SNP) | VAF 14/106 reads (13%) | catalogued as COSV99674386; called by muse, mutect2
- NDEL1 | c.-162G>A | 5'UTR (SNP) | VAF 106/497 reads (21%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790315 A>T | 5'Flank (SNP) | VAF 12/175 reads (7%) | catalogued as rs1356638709; called by muse, mutect2
